Somatic mutation profile of tumor specimen TCGA-DK-AA74-01A (aliquot TCGA-DK-AA74-01A-11D-A391-08) from TCGA case TCGA-DK-AA74, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Dome of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 75.9 years (27,730 days).
Specimen TCGA-DK-AA74-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a94c4159-9dbb-4aa9-aa94-c253c4f83ddd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DK-AA74-10A (Blood Derived Normal), aliquot TCGA-DK-AA74-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8cef621f-ca7e-4539-8934-39bbb0be3656

The open-access MAF lists 219 somatic variants for this specimen: 175 protein-altering or splice-affecting, 41 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 150, Silent 41, Nonsense Mutation 21, Splice Site 3, Splice Region 1, 3'UTR 1, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1B | c.1618C>T p.Q540* | Nonsense Mutation (SNP) | VAF 5/83 reads (6%) | catalogued as rs1554256703, COSV99266603; ClinVar: pathogenic; called by muse, mutect2
- DMD | c.5641C>T p.Q1881* | Nonsense Mutation (SNP) | VAF 13/37 reads (35%) | catalogued as rs863225004, CM013376, COSV100817316; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACSS2 | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 41/357 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.969); catalogued as rs372652815; called by muse, mutect2, varscan2
- AP2A2 | c.2515C>T p.Q839* | Nonsense Mutation (SNP) | VAF 10/36 reads (28%) | catalogued as COSV100172379; called by muse, mutect2, varscan2
- AP5M1 | c.397G>C p.E133Q | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1411256678, COSV99840940; called by muse, mutect2
- AP5M1 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55105935; called by muse, mutect2
- APOB | c.8392G>C p.E2798Q | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.138); catalogued as COSV51937332, COSV51941794; called by muse, mutect2
- ARC | c.960G>T p.E320D | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as COSV63078960; called by muse, mutect2, varscan2
- ARPP21 | c.401C>G p.S134* | Nonsense Mutation (SNP) | VAF 8/114 reads (7%) | catalogued as COSV51805626, COSV99490561; called by muse, mutect2
- ARSH | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.071); catalogued as COSV66963310; called by muse, mutect2, varscan2
- ASCC3 | c.6401G>C p.G2134A | Missense Mutation (SNP) | VAF 19/208 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.348); catalogued as COSV64977281; called by muse, mutect2
- ATR | c.6442C>T p.R2148* | Nonsense Mutation (SNP) | VAF 13/91 reads (14%) | catalogued as rs1455160611, COSV100637579; called by muse, mutect2, varscan2
- BMP3 | c.749C>G p.S250C | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as COSV51082185, COSV51082245, COSV51088256; called by muse, mutect2
- C12orf45 | c.190G>C p.E64Q | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.082); catalogued as rs1347819210, COSV55012913; called by muse, mutect2, varscan2
- C3 | c.3982G>A p.E1328K | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.161); catalogued as COSV55575652; called by muse, mutect2, varscan2
- CASP8 | c.1013C>G p.S338C (on ENST00000432109 / NM_033355.3; = p.S355C on NM_001228.4) | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as COSV51852824, COSV51861829; called by muse, mutect2
- CCDC158 | c.244G>C p.E82Q | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV66356519; called by muse, mutect2
- CD47 | c.867G>A p.M289I | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.191); catalogued as COSV62527604; called by muse, mutect2
- CDC27 | c.874C>T p.P292S | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.37); catalogued as COSV50439421; called by muse, mutect2
- CDC45 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV54245622, COSV54246532; called by muse, mutect2, varscan2
- CENPB | c.563C>T p.S188L | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.105); catalogued as rs1280523528, COSV60148009; called by muse, mutect2, varscan2
- CHMP2B | c.75G>C p.Q25H | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as COSV55462916; called by muse, mutect2, varscan2
- CHRNB2 | c.1490C>G p.S497* | Nonsense Mutation (SNP) | VAF 14/79 reads (18%) | catalogued as COSV100872516; called by muse, mutect2, varscan2
- CMPK1 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.632); catalogued as COSV64102066; called by muse, mutect2, varscan2
- CSRNP3 | c.1561G>A p.E521K | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.051); catalogued as rs1262600557, COSV58781091; called by muse, mutect2, varscan2
- CUBN | c.1009C>G p.P337A | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64719962; called by muse, mutect2
- DCAF17 | c.751G>C p.D251H | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); catalogued as COSV59830648; called by muse, mutect2
- DCBLD1 | c.1534C>T p.Q512* | Nonsense Mutation (SNP) | VAF 18/99 reads (18%) | catalogued as COSV99756948; called by muse, mutect2, varscan2
- DCHS1 | c.7917C>G p.F2639L | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as COSV54998587; called by muse, mutect2, varscan2
- DCTN4 | c.1243G>A p.V415M | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778708391, COSV69782508; called by muse, mutect2, varscan2
- DEPDC1 | c.1282G>C p.D428H | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); catalogued as COSV63958560; called by muse, mutect2
- DHX37 | c.859C>T p.Q287* | Nonsense Mutation (SNP) | VAF 14/158 reads (9%) | catalogued as COSV100438900; called by muse, mutect2
- DLEC1 | c.967C>T p.R323W | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370478680; called by muse, mutect2, varscan2
- DLG1 | c.59C>G p.S20* | Nonsense Mutation (SNP) | VAF 19/97 reads (20%) | catalogued as COSV100014475, COSV58385846; called by muse, mutect2, varscan2
- DNAH11 | c.6608T>G p.L2203* | Nonsense Mutation (SNP) | VAF 5/37 reads (14%) | catalogued as COSV100176376; called by muse, mutect2, varscan2
- DNAH12 | c.398G>C p.R133T | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.024); catalogued as COSV60857522; called by muse, mutect2
- DNAH5 | c.10813G>A p.D3605N | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1414807, COSV54236191; called by muse, mutect2
- EGF | c.3610G>T p.E1204* | Nonsense Mutation (SNP) | VAF 10/104 reads (10%) | catalogued as COSV99490354; called by muse, mutect2
- EMC4 | c.377C>A p.S126* | Nonsense Mutation (SNP) | VAF 13/108 reads (12%) | catalogued as COSV99970783; called by muse, mutect2, varscan2
- EVI5 | c.733C>G p.Q245E | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.423); catalogued as COSV63278724; called by muse, mutect2, varscan2
- FARSB | c.594G>A p.M198I | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.59); catalogued as COSV56050654, COSV99918208; called by muse, mutect2
- FBN2 | c.3106G>A p.E1036K | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.066); catalogued as rs773473369, COSV52496223; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FMN2 | c.1384G>A p.V462I | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.007); catalogued as COSV100142119; called by muse, mutect2
- FREM1 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1228729405, COSV101085932, COSV66526022; called by muse, mutect2
- FUBP1 | c.1064G>T p.G355V | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.883); catalogued as COSV53933617; called by muse, mutect2, varscan2
- GBP4 | c.839C>T p.S280L | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.02); catalogued as COSV63254970; called by muse, mutect2, varscan2
- GCN1 | c.2460C>G p.I820M | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.138); catalogued as COSV100324525; called by muse, mutect2
- GEMIN2 | c.52G>T p.E18* | Nonsense Mutation (SNP) | VAF 7/36 reads (19%) | catalogued as COSV99158009; called by muse, mutect2, varscan2
- GNPTAB | c.2535G>C p.Q845H | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV68449751; called by muse, mutect2, varscan2
- GOLGA4 | c.1760C>G p.S587* | Nonsense Mutation (SNP) | VAF 14/69 reads (20%) | catalogued as COSV100728602; called by muse, mutect2, varscan2
- GRIK2 | c.1174A>G p.I392V | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.014); catalogued as COSV100022134; called by muse, mutect2
- GRPEL1 | c.270G>C p.Q90H | Missense Mutation (SNP) | VAF 35/148 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV53827563; called by muse, mutect2, varscan2
- GSKIP | c.112G>C p.E38Q | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.852); catalogued as rs1260460042, COSV68451395; called by muse, mutect2
- GTDC1 | c.1204G>A p.E402K (on ENST00000344850 / NM_001354361.1; = p.E317K on NM_024659.6 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.862); catalogued as COSV53998827; called by muse, mutect2, varscan2
- HCLS1 | c.268G>C p.E90Q | Missense Mutation (SNP) | VAF 24/226 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.759); catalogued as rs1264241240, COSV58857826; called by muse, mutect2
- HFM1 | c.2249T>A p.L750* | Nonsense Mutation (SNP) | VAF 5/96 reads (5%) | catalogued as COSV99645155; called by muse, mutect2
- HMCN1 | c.2281G>A p.E761K | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.968); catalogued as COSV54878724; called by muse, mutect2, varscan2
- HOXC6 | c.319G>C p.E107Q | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.017); catalogued as COSV54537408, COSV99678893; called by muse, mutect2
- HSPA8 | c.1460A>G p.N487S | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.145); catalogued as rs749707173, COSV57084610; called by muse, mutect2, varscan2
- HYDIN | c.11470G>C p.E3824Q | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.758); catalogued as COSV66639979; called by muse, mutect2, varscan2
- IL1R1 | c.200C>G p.S67C | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.14); catalogued as COSV52106820; called by muse, mutect2
- ITIH2 | c.872T>C p.F291S | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.138); catalogued as COSV64433977; called by muse, mutect2
- ITIH2 | c.2161G>C p.D721H | Missense Mutation (SNP) | VAF 22/434 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV64433983; called by muse, mutect2
- KAT6A | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); catalogued as COSV55905688; called by muse, mutect2, varscan2
- KCNE3 | c.302C>T p.S101F | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100035497; called by muse, mutect2
- KIAA1549L | c.4586C>G p.S1529C (on ENST00000321505; = p.S1826C on NM_012194.3) | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV58592191; called by muse, mutect2, varscan2
- KIAA1755 | c.540G>C p.K180N | Missense Mutation (SNP) | VAF 8/125 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV54077994; called by muse, mutect2
- KIF16B | c.221C>T p.S74L | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as COSV61708658; called by muse, mutect2, varscan2
- LARP4 | c.1986G>C p.E662D | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.115); catalogued as COSV53324046; called by muse, mutect2
- LPAR1 | c.48C>G p.F16L | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as COSV62689788; called by muse, mutect2, varscan2
- LRIG2 | c.1340G>A p.C447Y | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV63162871; called by muse, mutect2, varscan2
- LRRC73 | c.270C>G p.L90= | Splice Region (SNP) | VAF 6/29 reads (21%) | catalogued as rs932324660, COSV52501842; called by muse, mutect2, varscan2
- LRRN4 | c.781C>G p.Q261E | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as COSV66645912, COSV66646372; called by muse, mutect2
- MAN2C1 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51231277; called by muse, mutect2, varscan2
- MCAM | c.1858G>C p.E620Q | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50644539; called by muse, mutect2, varscan2
- MCMDC2 | c.1406G>A p.R469K | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58037510; called by muse, mutect2, varscan2
- MED1 | c.4103C>T p.S1368F | Missense Mutation (SNP) | VAF 13/146 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.157); catalogued as COSV56126401; called by muse, mutect2
- MICB | c.489G>A p.M163I | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV99357279; called by muse, mutect2
- MIF4GD | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 17/173 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.039); catalogued as COSV55453787, COSV99821632; called by muse, mutect2, varscan2
- MKI67 | c.2251G>C p.D751H | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64075315; called by muse, mutect2, varscan2
- MNDA | c.653A>T p.K218I | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV63741279; called by muse, mutect2, varscan2
- MSTN | c.262C>T p.R88W | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs1315783994, COSV53621476; called by muse, mutect2, varscan2
- MYL12A | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.593); catalogued as COSV54182634; called by muse, mutect2, varscan2
- MYO1A | c.640+2T>C p.X214_splice | Splice Site (SNP) | VAF 14/108 reads (13%) | catalogued as COSV55655213; called by muse, mutect2, varscan2
- MYT1 | c.1538C>T p.A513V | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60501638, COSV60508687; called by muse, mutect2, varscan2
- NEXMIF | c.631A>G p.K211E | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV50046859; called by muse, mutect2, varscan2
- NKAIN2 | c.324G>C p.W108C | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV63671087, COSV63672477; called by muse, mutect2, varscan2
- NLGN4Y | c.1663G>C p.E555Q | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.887); catalogued as COSV59297439; called by muse, mutect2, varscan2
- NUDT11 | c.265C>G p.R89G | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.45); catalogued as COSV65665258; called by muse, mutect2
- NYNRIN | c.3440C>T p.S1147F | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as rs1368877167, COSV66843351; called by muse, mutect2, varscan2
- OPA1 | c.1306-1G>C p.X436_splice (on ENST00000361510 / NM_130837.3; = p.X381_splice on NM_015560.3) | Splice Site (SNP) | VAF 6/64 reads (9%) | catalogued as COSV62481728; called by muse, mutect2
- OR2K2 | c.812C>T p.A271V (on ENST00000374428; = p.A242V on NM_205859.2) | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100235075; called by mutect2, varscan2
- OR4B1 | c.300C>A p.F100L | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58883268; called by muse, mutect2, varscan2
- OR51A2 | c.254G>A p.S85N | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.09); catalogued as rs369202020; called by muse, mutect2, varscan2
- OR5B12 | c.486C>G p.F162L | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.246); catalogued as COSV56905395, COSV56905654; called by muse, mutect2, varscan2
- OR8I2 | c.809C>T p.A270V | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs749476782, COSV56166494, COSV56170718; called by muse, mutect2, varscan2
- OTOF | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); catalogued as rs370475628; called by mutect2, varscan2
- PAOX | c.974T>A p.L325Q | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53373140; called by muse, mutect2
- PAPPA2 | c.2353G>T p.E785* | Nonsense Mutation (SNP) | VAF 14/91 reads (15%) | catalogued as COSV100866460; called by muse, mutect2, varscan2
- PAWR | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 12/153 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.395); catalogued as rs1485892110, COSV60923606; called by muse, mutect2
- PCDHGA2 | c.1287C>A p.N429K | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as rs774533218, COSV53977872; called by muse, mutect2, varscan2
- PDZD2 | c.6073G>C p.E2025Q | Missense Mutation (SNP) | VAF 18/280 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV56863240; called by muse, mutect2
- PFDN5 | c.15T>G p.I5M | Missense Mutation (SNP) | VAF 10/153 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.388); catalogued as COSV54476349; called by muse, mutect2
- PHLDB2 | c.3419C>G p.S1140* (on ENST00000393925 / NM_001134439.2; = p.S1097* on NM_145753.2) | Nonsense Mutation (SNP) | VAF 9/91 reads (10%) | catalogued as COSV101208351; called by muse, mutect2, varscan2
- PIP4K2C | c.803G>C p.R268T | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.315); catalogued as COSV61606532; called by muse, mutect2
- PIP4K2C | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.438); catalogued as COSV61606536; called by muse, mutect2, varscan2
- PKHD1L1 | c.9583G>A p.E3195K | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as rs887970462, COSV65746578; called by muse, mutect2, varscan2
- PPARD | c.149C>T p.S50L | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs200198406; called by muse, mutect2, varscan2
- PPARGC1A | c.938C>T p.S313F | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53529833; called by muse, mutect2, varscan2
- PPFIA1 | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV54136970; called by muse, mutect2, varscan2
- PPP1R16B | c.1630C>G p.P544A | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55379747, COSV55380289; called by muse, mutect2, varscan2
- PRAMEF12 | c.256G>C p.D86H | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV63215808; called by muse, mutect2, varscan2
- PRF1 | c.845A>T p.K282M | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.375); catalogued as COSV64615317; called by muse, mutect2, varscan2
- PRF1 | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV64615321; called by muse, varscan2
- PRICKLE1 | c.1603G>T p.D535Y | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV58208230; called by muse, mutect2
- PRKCH | c.1708G>A p.E570K | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as COSV60649742; called by muse, mutect2, varscan2
- PTDSS1 | c.370G>C p.E124Q | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.142); catalogued as COSV61265032, COSV61265320; called by muse, mutect2, varscan2
- PTGER4 | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); catalogued as COSV100201375; called by muse, mutect2
- PUM2 | c.1855C>G p.P619A | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs1479006101, COSV57582843; called by muse, mutect2, varscan2
- PXYLP1 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV53891668; called by muse, mutect2
- RETSAT | c.1496C>T p.S499L | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.148); catalogued as COSV99805810; called by muse, mutect2
- RYR2 | c.5413C>T p.H1805Y | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.161); catalogued as rs867966757, COSV63695069; called by muse, mutect2, varscan2
- SCNN1G | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100263832; called by muse, mutect2
- SEL1L | c.2224G>C p.E742Q | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.532); catalogued as COSV60921216; called by muse, mutect2, varscan2
- SEMA3C | c.1355-1G>C p.X452_splice | Splice Site (SNP) | VAF 7/60 reads (12%) | catalogued as COSV54849764; called by muse, mutect2, varscan2
- SGMS1 | c.6G>C p.K2N | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV62371164; called by muse, mutect2, varscan2
- SHC4 | c.31G>T p.G11* | Nonsense Mutation (SNP) | VAF 9/120 reads (8%) | catalogued as COSV100194111; called by muse, mutect2
- SLC16A4 | c.794G>T p.G265V | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.524); catalogued as COSV63916905; called by muse, mutect2
- SLCO1A2 | c.170T>C p.L57P | Missense Mutation (SNP) | VAF 18/223 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs1038951024, COSV56605495; called by muse, mutect2
- SMARCAD1 | c.334G>C p.E112Q | Missense Mutation (SNP) | VAF 7/164 reads (4%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.102); catalogued as COSV62775130; called by muse, mutect2
- SMARCC1 | c.2086A>G p.M696V | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.114); catalogued as COSV54382997; called by muse, mutect2, varscan2
- SMG5 | c.379C>G p.L127V | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV62436210; called by muse, mutect2, varscan2
- SMG7 | c.3346G>C p.E1116Q | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); catalogued as COSV61632473; called by muse, mutect2
- SPAG1 | c.2162A>G p.D721G | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as rs1202317609, COSV52560971; called by muse, mutect2, varscan2
- SPANXN2 | c.4G>C p.E2Q | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100979895, COSV65128776; called by muse, mutect2, varscan2
- SPARCL1 | c.1123C>G p.Q375E | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.078); catalogued as COSV56804881; called by muse, mutect2
- SPATA31E1 | c.4109G>C p.R1370T | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs772777500, COSV57793103; called by muse, mutect2, varscan2
- SPPL2C | c.2016G>C p.L672F | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as COSV61292981; called by muse, mutect2, varscan2
- SRRM2 | c.4285G>C p.D1429H | Missense Mutation (SNP) | VAF 12/159 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.781); catalogued as COSV57076075; called by muse, mutect2
- SSX2IP | c.401T>C p.L134P | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60553458; called by muse, mutect2
- TBCB | c.73G>C p.E25Q | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.211); catalogued as COSV99387413; called by muse, mutect2
- TBX19 | c.191C>G p.T64S | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100892448, COSV63197871; called by muse, mutect2
- TEC | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV67405411; called by muse, mutect2, varscan2
- TET3 | c.2274G>C p.K758N | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV99996118; called by muse, mutect2
- TGM4 | c.1735G>A p.E579K | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as rs760781069, COSV56094838; called by muse, mutect2, varscan2
- THADA | c.2143G>A p.E715K | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV57687149; called by muse, mutect2, varscan2
- THSD7A | c.3904T>C p.C1302R | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101439710; called by muse, varscan2
- THY1 | c.177G>C p.K59N | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.502); catalogued as COSV52454692; called by muse, mutect2
- TIAM2 | c.3487G>A p.D1163N | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs766184932, COSV51641934; called by muse, mutect2, varscan2
- TMEM87A | c.814G>C p.E272Q | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV67746325, COSV67747277; called by muse, mutect2
- TNC | c.2257G>C p.D753H | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60786730; called by muse, mutect2, varscan2
- TNIK | c.776C>A p.S259* | Nonsense Mutation (SNP) | VAF 4/26 reads (15%) | catalogued as COSV99454396; called by muse, mutect2
- TNIK | c.774G>T p.W258C | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52686800; called by muse, mutect2
- TSSK4 | c.304C>G p.L102V | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV55303784; called by muse, mutect2, varscan2
- TTC3 | c.3850G>C p.E1284Q | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.537); catalogued as COSV61292598; called by muse, mutect2, varscan2
- TTC6 | c.851G>C p.R284T (on ENST00000267368; = p.R1650T on NM_001310135.3) | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57450372; called by muse, mutect2, varscan2
- UACA | c.3488C>T p.S1163F | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59857267; called by muse, mutect2
- UACA | c.3487T>A p.S1163T | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV59857276; called by muse, mutect2
- UBE2T | c.361G>T p.D121Y | Missense Mutation (SNP) | VAF 36/264 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.74); catalogued as COSV66153364, COSV66153477; called by muse, varscan2
- UBE2T | c.201G>T p.Q67H | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV66153482; called by muse, mutect2, varscan2
- UBP1 | c.1557G>C p.E519D | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV52146352; called by muse, mutect2, varscan2
- UBQLN1 | c.1225C>T p.Q409* | Nonsense Mutation (SNP) | VAF 13/61 reads (21%) | catalogued as COSV99973061; called by muse, mutect2, varscan2
- UGT3A1 | c.128C>G p.S43C | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57099814; called by muse, mutect2, varscan2
- UHRF1BP1L | c.2161T>G p.S721A | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV54439326; called by muse, mutect2, varscan2
- USP37 | c.496C>G p.P166A | Missense Mutation (SNP) | VAF 5/116 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.368); catalogued as COSV51444817; called by muse, mutect2
- ZACN | c.128C>A p.S43Y | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.2); catalogued as COSV58036806; called by muse, mutect2, varscan2
- ZBTB21 | c.1162G>C p.D388H | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV100176838; called by muse, mutect2
- ZBTB44 | c.1336C>T p.R446C | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.094); catalogued as COSV63537648; called by muse, mutect2
- ZFHX4 | c.8326G>A p.E2776K | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV51458869; called by muse, mutect2, varscan2
- ZMAT2 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.03); catalogued as COSV99217951; called by muse, mutect2
- ZNF14 | c.1064G>C p.R355T | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV59850241, COSV59850626; called by muse, mutect2, varscan2
- ZNF189 | c.977G>A p.R326Q | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.916); catalogued as rs776011149, COSV52275799; called by muse, mutect2, varscan2
- ZNF230 | c.712A>C p.I238L | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV71273512; called by muse, mutect2
- ZNF347 | c.2165C>G p.S722* | Nonsense Mutation (SNP) | VAF 13/159 reads (8%) | catalogued as rs778533690, COSV100498090; called by muse, mutect2
- PARP14 | c.2542G>A p.D848N | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.808); called by muse, mutect2
- AADAC | c.942C>T p.F314= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as rs1421998643, COSV51758253, COSV51760088; called by muse, mutect2, varscan2
- ACACB | c.4062C>T p.F1354= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV58138670; called by muse, mutect2, varscan2
- AKAP12 | c.3772C>T p.L1258= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as COSV53577637, COSV99482812; called by muse, mutect2, varscan2
- ARC | c.207G>A p.G69= | Silent (SNP) | VAF 2/16 reads (13%) | called by muse, mutect2
- AUTS2 | c.3537C>T p.L1179= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs71549378, COSV61414043; called by muse, mutect2, varscan2
- BMP5 | c.45C>G p.L15= | Silent (SNP) | VAF 31/156 reads (20%) | catalogued as COSV63704494; called by muse, mutect2, varscan2
- CAND2 | c.3027G>A p.L1009= (on ENST00000456430 / NM_001162499.2; = p.L916= on NM_012298.3) | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as COSV55991598; called by muse, mutect2, varscan2
- CASP8 | c.930C>T p.F310= (on ENST00000432109 / NM_033355.3; = p.F327= on NM_001228.4) | Silent (SNP) | VAF 8/130 reads (6%) | catalogued as COSV51853898; called by muse, mutect2
- CDH7 | c.1044C>T p.A348= | Silent (SNP) | VAF 7/67 reads (10%) | catalogued as rs1335721867, COSV59888758; called by muse, mutect2, varscan2
- CELSR2 | c.4920C>T p.L1640= | Silent (SNP) | VAF 16/86 reads (19%) | catalogued as COSV54767219, COSV54774792; called by muse, mutect2, varscan2
- CTTN | c.948G>A p.R316= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as COSV57232306; called by muse, mutect2, varscan2
- CYLD | c.2217C>T p.I739= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as COSV61092933, COSV61095795; called by muse, mutect2, varscan2
- EML5 | c.3771C>T p.G1257= | Silent (SNP) | VAF 8/113 reads (7%) | catalogued as rs1024660402, COSV61347905; called by muse, mutect2
- FCRL5 | c.672C>G p.L224= | Silent (SNP) | VAF 9/131 reads (7%) | catalogued as COSV62516518, COSV62521378; called by muse, mutect2
- FLNC | c.6693G>A p.L2231= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs1420281069, COSV57958693; called by muse, varscan2
- GATAD2A | c.873C>T p.L291= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as rs756000158, COSV53072322; called by mutect2, varscan2
- GIT1 | c.1044C>T p.L348= | Silent (SNP) | VAF 24/176 reads (14%) | catalogued as COSV56403049; called by muse, mutect2, varscan2
- GRAMD4 | c.1491C>T p.F497= | Silent (SNP) | VAF 16/191 reads (8%) | catalogued as rs145491235; called by muse, mutect2
- HPCAL1 | c.456C>T p.I152= | Silent (SNP) | VAF 14/75 reads (19%) | catalogued as rs1486817489, COSV57147210; called by muse, mutect2, varscan2
- HSD17B8 | c.636G>A p.Q212= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as rs1485121129, COSV63002700; called by muse, mutect2, varscan2
- IGFL3 | c.132G>A p.G44= | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as rs771748649, COSV58242480, COSV58242964; called by muse, mutect2, varscan2
- ITGAL | c.3465G>T p.L1155= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV63322969; called by muse, mutect2, varscan2
- JUN | c.237G>C p.L79= | Silent (SNP) | VAF 7/91 reads (8%) | catalogued as rs1286135805, COSV64664653; called by muse, mutect2
- LDLR | c.378C>T p.F126= | Silent (SNP) | VAF 30/224 reads (13%) | catalogued as rs762139262, COSV52944234; ClinVar: benign; called by muse, mutect2, varscan2
- LPAR1 | c.366C>G p.L122= | Silent (SNP) | VAF 23/111 reads (21%) | catalogued as rs1347596365, COSV62689781; called by muse, mutect2, varscan2
- OR14A16 | c.111G>A p.L37= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as COSV62926524; called by muse, mutect2
- OR5D14 | c.498C>T p.L166= | Silent (SNP) | VAF 16/134 reads (12%) | catalogued as COSV59455405; called by muse, mutect2, varscan2
- OR6C76 | c.504C>T p.S168= | Silent (SNP) | VAF 16/113 reads (14%) | catalogued as COSV100094120, COSV60389352; called by muse, mutect2, varscan2
- PACC1 | c.930C>T p.L310= | Silent (SNP) | VAF 12/84 reads (14%) | catalogued as COSV54788574; called by muse, mutect2, varscan2
- PLBD2 | c.1734C>G p.L578= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as COSV55107602; called by muse, mutect2, varscan2
- PRF1 | c.846G>A p.K282= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV64615311; called by mutect2, varscan2
- SGCZ | c.675G>A p.V225= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as rs772554821, COSV66024046; called by mutect2, varscan2
- SLC22A10 | c.765C>T p.F255= | Silent (SNP) | VAF 9/108 reads (8%) | catalogued as rs747767575, COSV60422063; called by muse, mutect2
- SLC22A7 | c.1092G>C p.L364= (on ENST00000372585 / NM_153320.2; = p.L362= on NM_006672.3) | Silent (SNP) | VAF 6/84 reads (7%) | catalogued as COSV51484654; called by muse, mutect2
- SLCO5A1 | c.120C>T p.V40= | Silent (SNP) | VAF 12/97 reads (12%) | catalogued as COSV52662278; called by muse, mutect2, varscan2
- STK32B | c.453T>C p.N151= | Silent (SNP) | VAF 33/136 reads (24%) | catalogued as COSV51497013; called by muse, mutect2, varscan2
- SUPT20HL1 | c.1179C>G p.L393= | Silent (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2
- SYT1 | c.570G>A p.K190= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as COSV54057125; called by muse, mutect2, varscan2
- TAS2R40 | c.765C>T p.L255= | Silent (SNP) | VAF 9/99 reads (9%) | catalogued as rs1563036344, COSV68818513; called by muse, mutect2
- TRIM7 | c.909C>T p.V303= | Silent (SNP) | VAF 3/37 reads (8%) | catalogued as COSV99219929; called by muse, mutect2
- UNC79 | c.7321C>T p.L2441= (on ENST00000393151 / NM_001346218.2; = p.L2264= on NM_020818.5) | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as COSV56395731; called by muse, mutect2
- ABHD3 | c.555+408A>G | Intron (SNP) | VAF 10/75 reads (13%) | catalogued as COSV100004147; called by muse, mutect2, varscan2
- ENPP4 | c.*2_*9del | 3'UTR (DEL) | VAF 14/159 reads (9%) | called by mutect2, pindel
- PRDM15 | c.-217G>C | 5'UTR (SNP) | VAF 8/39 reads (21%) | catalogued as COSV54155363; called by muse, mutect2
